Surgical pathology report (de-identified scan), TCGA case TCGA-KN-8435, project TCGA-KICH (Kidney Chromophobe), tissue source site Harvard, specimen TCGA-KN-8435-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS:

1. Right kidney:

Renal cell carcinoma, see synoptic report.

2. Tissue from vena cava:

Nodular piece of fibrovascular tissue. No lymph node identified.

Kidney: Nephrectomy, partial or radical Synopsis

MACROSCOPIC

Specimen Type: Right radical nephrectomy.

Focality: Unifocal.

Tumor Size

One dimension: 8.0 cm.

Macroscopic extent of tumor: Tumor limited to kidney.

MICROSCOPIC

Histologic Type:

Chromophobe renal cell carcinoma.

[page 2 of 2]
[REDACTED]

Histologic Grade: G2: Nuclei slightly irregular, approximately 15 microns; nucleoli evident;.

EXTENT OF INVASION

Primary Tumor: pT2: Tumor more than 7 cm in greatest dimension, limited to the kidney.

Regional Lymph Nodes: pNX: Cannot be assessed.

Lymph Nodes: None submitted.

Distant metastasis: pMX: Cannot be assessed.

Margins:

Margins uninvolved by invasive carcinoma.

Venous invasion: Absent.

Additional Pathologic Findings: Inflammation (type): chronic. Tumor cells stain for colloidal iron.

Clinical: Renal carcinoma - right kidney;

Gross:

Part 1 is received fresh and additionally labeled with [REDACTED] and "right kidney." The specimen consists of a kidney specimen with perinephric fat that measures 19 cm x 17 cm x 10 cm. The ureter is patent. The specimen is inked in black, and breadloafed to reveal an 8.3 cm mass within the kidney parenchyma that grossly abuts the perinephric fat. The tumor has two distinct areas one area is tan and hemorrhagic, and measures 6.2 cm x 6 cm x 4 cm. The other part of the mass is a nodule that measures 4.3 cm x 4 cm x 2.5 cm. The ureteral margin is in A and the vascular margins are in B. A random section of tumor is in C. The tumor with respect to perinephric fat is in D, the tumor with respect to inked margin is in E. Representative sections of the tumor with respect to fat with resection margin is ink F. Representative sections of the tumor are in G-J. K = representative sections of tumor with fat and inked capsule, L = representative sections of tumor with respect to kidney parenchyma. M = representative sections of kidney parenchyma not effected by the tumor and contains representative sections of lymph nodes from the hilum. O = another representative sections of tumor.

Part 2 is additionally labeled "venacaval lymph node". It consists of a 0.7 x 0.5 cm fragment of [REDACTED] [REDACTED] tissue that is entirely submitted in P.

[REDACTED]

Source: NCI Genomic Data Commons file 283b98d2-02a5-4ce5-b560-3907309b4fc0 (TCGA-KN-8435.5DC00796-FB11-462C-A869-C0EB786CD295.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).